Gene-level copy-number profile of tumor specimen C3N-01859-01 from CPTAC case C3N-01859, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 67.3 years (24,594 days).
Specimen C3N-01859-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f031127c-acbf-4c53-b602-80c4fc1e244d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01859-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,232 have no estimate.
https://portal.gdc.cancer.gov/files/a59bed29-849a-455f-b42f-0607a39cec25

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 167; copy number 2: 2,314; copy number 3: 525; copy number 4: 21,545; copy number 5: 3,676; copy number 6: 21,208; copy number 7: 1,506; copy number 8: 4,127; copy number 9: 2,080; copy number 10: 229; copy number 11: 101; copy number 12: 263; copy number 13: 78; copy number 14: 130; copy number 15: 59; copy number 16: 213; copy number 17: 81; copy number 21: 9; copy number 29: 22; copy number 36: 14; copy number 54: 22.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,849,674–120,914,238, 4 genes (within-gene range 0–3): AC253572.1, RNVU1-19, PPIAL4A, AC241377.3.
- chr14:50,299,855–50,335,558, 3 genes (within-gene range 0–3): MIR4504, DMAC2L, AL359397.2.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 628 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:160,755,602–186,784,179, 393 genes, copy number 13–21 (within-gene range 12–21) (broad region; genes not listed).
- chr3:198,110,112–198,123,232, 3 genes, copy number 13: FRG2FP, TUBB8P8, AC073135.1.
- chr4:149,907,560–150,257,438, 5 genes, copy number 13: RNA5SP167, RNU6-1230P, AC105343.1, DCLK2, RNU7-194P.
- chr7:62,275,361–62,275,678, 1 gene, copy number 13: AC128676.1.
- chr7:63,768,257–66,858,136, 135 genes, copy number 15–17 (broad region; genes not listed).
- chr7:81,946,444–82,443,777, 2 genes, copy number 15: CACNA2D1, CACNA2D1-AS1.
- chr7:83,355,154–83,649,139, 4 genes, copy number 14: AC079799.1, SEMA3E, AC079799.2, AC079987.1.
- chr7:106,208,167–106,286,326, 3 genes, copy number 17: RNU6-392P, NAMPT, AC007032.1.
- chr8:41,645,177–42,405,937, 22 genes, copy number 13: NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3.
- chr11:68,870,664–70,398,488, 49 genes, copy number 29–54 (within-gene range 4–54): LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1.
- chr11:72,519,986–72,674,591, 9 genes, copy number 54: ART2P, AP005019.2, AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1.
- chr22:18,361,820–18,391,105, 2 genes, copy number 13: FAM230J, AC011718.1.

Autosomal genes at a single copy (total copy number 1): 167. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
